Gene-level copy-number profile of tumor specimen TCGA-19-2631-01A from TCGA case TCGA-19-2631, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 74.5 years (27,200 days).
Specimen TCGA-19-2631-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.06401308-f6d0-4dd2-b5f0-f4443f8f94a9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-19-2631-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c310a89e-f16d-4a79-b18c-f9a7e9e30db8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 4,633; copy number 2: 48,517; copy number 3: 6,606; copy number 5: 27; copy number 10: 1; copy number 11: 13; copy number 22: 4; copy number 24: 3; copy number 25: 2; copy number 27: 3; copy number 32: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-19-2631-01A-01D-1224-01): tumor purity 0.86, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 8 genes (within-gene range 0–1): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,009,305, 2 genes: AL449423.1, CDKN2B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 54 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:51,918,772–52,551,574, 9 genes, copy number 5: AC027271.1, AC104784.1, LRRC66, SGCB, LINC02480, SPATA18, AC097522.2, AC097522.1, RNU6-1252P.
- chr4:53,377,839–54,295,272, 1 gene, copy number 5 (within-gene range 2–5): AC058822.1.
- chr4:53,659,208–54,607,131, 17 genes, copy number 5: AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260.
- chr7:50,444,128–50,565,405, 3 genes, copy number 22 (within-gene range 2–22): FIGNL1, DDC, DDC-AS1.
- chr7:53,926,676–55,260,256, 20 genes, copy number 10–27: LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.
- chr7:55,436,056–55,595,006, 4 genes, copy number 24–32 (within-gene range 2–32): VOPP1, AC099681.1, AC099681.3, AC099681.2.

Autosomal genes at a single copy (total copy number 1): 4,633. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
